Somatic mutation profile of tumor specimen 0E0MJ6 from CCDI case PBCVGG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0MJ6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59bb5b5b-dd51-4319-918b-2bd01704616a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0MJW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d76a0e4a-ed6c-41da-b636-4d07bc5375c2

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCAR1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 369/1086 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs748256307, COSV56268129, COSV56268161; called by muse, mutect2, varscan2
- RAB25 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 544/2003 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 30/1146 reads (3%) | called by muse, mutect2
